MMRF case MMRF_2316 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e863eb6f-a0cb-419f-bee3-f5309ae3b7aa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.4 years (23,530 days); ISS stage: III; Days to last known disease status: 859 days (2.4 years); Days to last follow up: 859 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 144 days; Days to treatment end: 144 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 3.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 209 mg/dL; Immunoglobulin G 48.5 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 20 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 655 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.03 mmol/L; Albumin 32 g/L; Total Protein 9.3 g/dL; Glucose 7.54 mmol/L; C-Reactive Protein 0.03 mg/dL.
- Day 79 (ECOG 1): M Protein 0.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.4 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 11 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 773 µmol/L; Blood Urea Nitrogen 24.6 mmol/L; Calcium 2.03 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 6.71 mmol/L.
- Day 208 (ECOG 0): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.28 mg/dL; Immunoglobulin G 8.37 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 4.53 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 8.02 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 681 µmol/L; Blood Urea Nitrogen 22.5 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 6.99 mmol/L.
- Day 302 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.81 mg/dL; Immunoglobulin G 7.96 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 4.78 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 12.5 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 800 µmol/L; Blood Urea Nitrogen 26.1 mmol/L; Calcium 1.9 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 8.58 mmol/L.
- Day 341 (ECOG 0): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.03 mg/dL; Immunoglobulin G 8.5 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.83 g/L; Lactate Dehydrogenase 5.3 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 553 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 7.87 mmol/L.
- Day 439 (ECOG 0): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.73 mg/dL; Immunoglobulin G 9.06 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 4.2 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 577 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 11.1 mmol/L.
- Day 548 (ECOG 0): M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.4 mg/dL; Immunoglobulin G 9.13 g/L; Immunoglobulin A 2.32 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 694 µmol/L; Blood Urea Nitrogen 17.9 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 9.35 mmol/L.
- Day 646 (ECOG 0): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.76 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.46 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.93 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 720 µmol/L; Blood Urea Nitrogen 28.6 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 14.1 mmol/L.
- Day 761 (ECOG 0): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.2 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.49 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 710 µmol/L; Blood Urea Nitrogen 25.3 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 16.6 mmol/L.
- Day 859 (ECOG 0): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 2.63 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 11.3 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 713 µmol/L; Blood Urea Nitrogen 24.3 mmol/L; Calcium 2.05 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 8.86 mmol/L.

Other clinical attributes
- Day 1: Weight: 94 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2316_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2316_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
